Somatic mutation profile of tumor specimen TCGA-H7-7774-01A (aliquot TCGA-H7-7774-01A-21D-2078-08) from TCGA case TCGA-H7-7774, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 75.3 years (27,519 days).
Specimen TCGA-H7-7774-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6352017d-eb4b-4620-8c0a-a50d00baa9fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-H7-7774-10A (Blood Derived Normal), aliquot TCGA-H7-7774-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fa396aa-6a38-4b96-86cd-c1acddc76acc

The open-access MAF lists 148 somatic variants for this specimen: 113 protein-altering or splice-affecting, 33 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 33, Nonsense Mutation 6, Frame Shift Ins 4, Frame Shift Del 3, Intron 2, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.88C>T p.L30F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960047; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 18/81 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 16/61 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs1554263326, COSV100640958, COSV61822452, COSV61823434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACSM2B | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.825); catalogued as COSV100312314; called by muse, mutect2, varscan2
- ADAMTSL1 | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.452); catalogued as COSV99440949; called by muse, mutect2, varscan2
- ADCY5 | c.1812C>G p.I604M | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100567312; called by muse, mutect2
- ADPGK | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.108); catalogued as COSV100295144; called by muse, mutect2
- AIG1 | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.8); PolyPhen benign (0.014); catalogued as rs1209745410, COSV99263238; called by muse, mutect2
- ALOX5 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs754256319, COSV65550760; called by muse, mutect2, varscan2
- ANKRD30A | c.3158G>C p.G1053A (on ENST00000611781; = p.G997A on NM_052997.2) | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV100652931; called by muse, mutect2
- APOL2 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); catalogued as rs764422788, COSV99969060; called by muse, mutect2, varscan2
- ARHGAP36 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV52271725; called by muse, mutect2, varscan2
- ASIC4 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs370439074; called by muse, mutect2, varscan2
- BMP6 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.511); catalogued as rs201531160, COSV99306337; called by muse, varscan2
- C6orf62 | c.510_512del p.V171del | In Frame Del (DEL) | VAF 16/103 reads (16%) | catalogued as rs1261411022; called by mutect2, pindel, varscan2
- CADM2 | c.325A>T p.M109L (on ENST00000407528 / NM_001167674.2; = p.M111L on NM_153184.4) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.874); catalogued as COSV101052837; called by muse, mutect2, varscan2
- CELSR2 | c.3182C>T p.T1061I | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99603046; called by muse, mutect2, varscan2
- CEP350 | c.9301A>G p.I3101V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as rs150197968; called by muse, mutect2, varscan2
- CHD7 | c.6293G>A p.R2098Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as rs375199214; called by muse, mutect2, varscan2
- CLOCK | c.1427G>C p.R476T | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.694); catalogued as COSV100011595; called by muse, mutect2, varscan2
- COX5B | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1337852306, COSV99300231; called by muse, mutect2
- CREBBP | c.2879C>G p.P960R | Missense Mutation (SNP) | VAF 62/308 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52117428, COSV99268579; called by muse, mutect2, varscan2
- CSMD3 | c.6502C>T p.R2168* (on ENST00000297405 / NM_001363185.1; = p.R2064* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV52093221; called by muse, mutect2, varscan2
- CTNNA3 | c.2078T>A p.I693K | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV101041244; called by muse, mutect2, varscan2
- CUL5 | c.696A>T p.K232N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.389); catalogued as COSV101263635; called by muse, mutect2, varscan2
- DCAF10 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); catalogued as COSV54287205, COSV99647540; called by muse, varscan2
- DIS3 | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100899824; called by muse, mutect2, varscan2
- DLGAP2 | c.2317G>A p.V773I | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs34274599, COSV70097003; called by muse, mutect2, varscan2
- EP300 | c.4167C>G p.N1389K | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99607134, COSV99607371; called by muse, mutect2
- EPHA3 | c.1903G>T p.V635L | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV100342917; called by muse, mutect2, varscan2
- FAM47A | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.293); catalogued as rs778609166, COSV100649727, COSV100649972; called by muse, mutect2, varscan2
- FAT1 | c.10672G>T p.E3558* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as COSV101499017; called by muse, mutect2, varscan2
- FAT1 | c.7877G>A p.G2626D | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1387437743, COSV101499018; called by muse, mutect2, varscan2
- FAT4 | c.14441G>T p.R4814M | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV58690027, COSV58690380; called by muse, mutect2, varscan2
- FBXO10 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.691); catalogued as rs778381633, COSV99446098; called by muse, mutect2, varscan2
- FHOD1 | c.3299C>A p.P1100H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.827); catalogued as COSV99263817; called by muse, mutect2, varscan2
- FKBPL | c.526C>T p.Q176* | Nonsense Mutation (SNP) | VAF 10/163 reads (6%) | catalogued as COSV100913535; called by muse, mutect2
- FMO1 | c.718C>G p.Q240E | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV100707692, COSV100707694; called by muse, mutect2
- GDA | c.679G>A p.G227S | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs749225604, COSV99428776; called by muse, mutect2, varscan2
- GPR75 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV100765861; called by muse, mutect2, varscan2
- GRB14 | c.868G>A p.V290M | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as COSV99813659; called by muse, mutect2, varscan2
- GSDME | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs529901453, COSV100742238, COSV100742354; called by muse, mutect2, varscan2
- H1-2 | c.263T>G p.V88G | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100642245; called by muse, mutect2, varscan2
- HIP1 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as COSV100416939; called by muse, mutect2, varscan2
- HS3ST5 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.706); catalogued as rs374141405; called by muse, mutect2, varscan2
- IGSF22 | c.1926C>A p.Y642* | Nonsense Mutation (SNP) | VAF 26/101 reads (26%) | catalogued as rs774341661, COSV100079159; called by muse, mutect2, varscan2
- IQSEC2 | c.1810G>A p.V604M (on ENST00000642864 / NM_001111125.3; = p.V399M on NM_015075.2) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.814); catalogued as rs1556863245, COSV100944735; called by muse, mutect2, varscan2
- ITPR2 | c.7978G>A p.V2660I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV101189813; called by muse, mutect2, varscan2
- ITPR2 | c.7043A>G p.Y2348C | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101189814; called by muse, mutect2, varscan2
- KCTD1 | c.489G>C p.L163F | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100517478; called by muse, mutect2
- KIF17 | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766360804, COSV56118559; called by muse, mutect2, varscan2
- KIRREL1 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs761300909, COSV63285186; called by muse, mutect2
- LTBP1 | c.1667T>C p.L556P (on ENST00000404816 / NM_206943.4; = p.L230P on NM_000627.4) | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616345; called by muse, mutect2, varscan2
- MAGEB3 | c.588G>T p.R196S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as COSV100854609, COSV100854848; called by muse, mutect2, varscan2
- MAP1A | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs750529589, COSV55807975; called by muse, mutect2, varscan2
- MAP7D3 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV100286170; called by muse, mutect2, varscan2
- MED24 | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.503); catalogued as COSV99842294; called by muse, mutect2, varscan2
- MEF2C | c.639G>A p.G213= | Splice Region (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100424588, COSV60931052; called by muse, mutect2, varscan2
- MMGT1 | c.284A>G p.H95R | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV100018375; called by muse, mutect2, varscan2
- MPP4 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV100206475; called by muse, mutect2, varscan2
- MRGPRX4 | c.836G>C p.R279T | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100049633; called by muse, mutect2, varscan2
- MYCBP2 | c.11569G>A p.E3857K (on ENST00000357337; = p.E3895K on NM_015057.5) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV62011582; called by muse, mutect2, varscan2
- MYH1 | c.3419G>A p.R1140H | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as rs779598062, COSV56846716; called by muse, mutect2, varscan2
- MYO1C | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs767997586, COSV99055299; called by muse, mutect2, varscan2
- MYO9A | c.7528C>T p.Q2510* | Nonsense Mutation (SNP) | VAF 40/133 reads (30%) | catalogued as COSV100612641; called by muse, mutect2, varscan2
- NFRKB | c.1709G>A p.R570H (on ENST00000446488 / NM_001143835.2; = p.R595H on NM_006165.3) | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs376035619, COSV100451787; called by muse, mutect2, varscan2
- NKAP | c.1193T>C p.L398P | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100538225; called by muse, mutect2, varscan2
- NPAS3 | c.1190G>A p.R397H (on ENST00000356141 / NM_001164749.2; = p.R365H on NM_022123.3) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60848336; called by muse, mutect2, varscan2
- OR13C4 | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99469972; called by muse, mutect2
- OR13C9 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99403342; called by muse, mutect2, varscan2
- OR2AT4 | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100532263; called by muse, mutect2
- OR4C11 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as rs141808171; called by muse, mutect2, varscan2
- OR5D13 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); catalogued as COSV100686717, COSV62335759; called by muse, mutect2
- OR6C65 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.344); catalogued as COSV101110169; called by muse, mutect2, varscan2
- PC | c.2890C>T p.R964C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs192822072, COSV58992428; called by muse, mutect2, varscan2
- PCDHA9 | c.2357C>T p.T786M | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV65325611; called by muse, mutect2, varscan2
- PKD1L1 | c.1875C>A p.D625E | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV99218439; called by muse, mutect2, varscan2
- PLXNA4 | c.4328C>T p.T1443I | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100322478; called by muse, mutect2, varscan2
- PPFIA4 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99829496; called by muse, mutect2, varscan2
- PPFIBP1 | c.1430G>T p.G477V (on ENST00000318304 / NM_177444.3; = p.G460V on NM_003622.4) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99944096; called by muse, mutect2, varscan2
- PRMT7 | c.1913G>A p.G638D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99545280; called by muse, mutect2
- PSMA1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV101123621; called by muse, mutect2, varscan2
- RAD54B | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100279383; called by muse, mutect2
- SETD2 | c.4723T>A p.F1575I | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100337994; called by muse, mutect2, varscan2
- SLC5A4 | c.1136G>A p.R379Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.379); catalogued as rs142416109, COSV56670279; called by muse, mutect2
- SLC7A10 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99471993; called by muse, mutect2, varscan2
- SLITRK1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65675812; called by muse, mutect2, varscan2
- SORCS3 | c.2637C>G p.I879M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100863392; called by muse, mutect2, varscan2
- SVEP1 | c.10457A>T p.N3486I | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.868); catalogued as COSV99928295; called by muse, mutect2, varscan2
- SVEP1 | c.6906G>A p.W2302* | Nonsense Mutation (SNP) | VAF 21/83 reads (25%) | catalogued as COSV99928298; called by muse, mutect2, varscan2
- TBC1D5 | c.1823A>G p.Y608C | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99509282; called by muse, mutect2, varscan2
- TCP11L1 | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV100177843; called by muse, mutect2, varscan2
- TRARG1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.158); catalogued as rs751171532, COSV61562502, COSV61563020; called by muse, mutect2, varscan2
- TRPM6 | c.4835C>T p.P1612L | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV100665357; called by muse, mutect2, varscan2
- USP9X | c.5348G>A p.R1783H | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100198490; called by muse, mutect2
- VCP | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV100734096; called by muse, mutect2, varscan2
- VEZF1 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.253); catalogued as rs761530449, COSV99365573, COSV99365928; called by muse, mutect2, varscan2
- VPS33B | c.1716C>G p.F572L | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100325422; called by muse, mutect2
- WAPL | c.1883A>T p.E628V | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99556276; called by muse, mutect2, varscan2
- WDR77 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99330695; called by muse, mutect2, varscan2
- ZCWPW2 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV101074522; called by muse, mutect2, varscan2
- ZDHHC16 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs748165827, COSV100620501; called by muse, mutect2, varscan2
- ZNF419 | c.362G>A p.S121N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.58); catalogued as COSV99691801; called by muse, mutect2, varscan2
- ZNF438 | c.2404G>C p.E802Q | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV100061241; called by muse, mutect2
- ZNF763 | c.569G>A p.R190H (on ENST00000358987 / NM_001367172.2; = p.R193H on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370964246; called by muse, mutect2, varscan2
- ZNF875 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV100183054; called by muse, mutect2, varscan2
- CTCF | c.1754_1766del p.G585Efs*42 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- GPS2 | c.931_932dup p.R312Lfs*34 | Frame Shift Ins (INS) | VAF 21/149 reads (14%) | called by mutect2, pindel, varscan2
- JMY | c.2709del p.H904Ifs*2 | Frame Shift Del (DEL) | VAF 22/105 reads (21%) | called by mutect2, pindel, varscan2
- KMT2C | c.11358_11362dup p.S3788Yfs*5 | Frame Shift Ins (INS) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- KRT5 | c.101_102dup p.V35Pfs*117 | Frame Shift Ins (INS) | VAF 23/77 reads (30%) | called by mutect2, pindel, varscan2
- TIGD4 | c.387dup p.N130* | Frame Shift Ins (INS) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- ZBTB32 | c.618_622del p.D206Efs*16 | Frame Shift Del (DEL) | VAF 11/51 reads (22%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.12141C>G p.L4047= | Silent (SNP) | VAF 9/221 reads (4%) | catalogued as COSV100315593; called by muse, mutect2
- ALG10 | c.879C>T p.Y293= | Silent (SNP) | VAF 44/161 reads (27%) | catalogued as COSV99847915; called by muse, mutect2, varscan2
- ANKRD12 | c.4512G>T p.S1504= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs74916798, COSV100040745; called by muse, mutect2, varscan2
- ANO5 | c.756C>A p.L252= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100201397, COSV61082054; called by mutect2, varscan2
- COL16A1 | c.2394C>T p.A798= | Silent (SNP) | VAF 48/204 reads (24%) | catalogued as COSV99593569; called by muse, mutect2, varscan2
- DPP8 | c.492C>T p.V164= (on ENST00000341861 / NM_001320875.2; = p.V148= on NM_017743.6) | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as rs748825550, COSV100202096; called by muse, mutect2, varscan2
- EIF3H | c.885G>T p.P295= | Silent (SNP) | VAF 46/195 reads (24%) | catalogued as COSV52663647, COSV99411450; called by muse, mutect2, varscan2
- FGF13 | c.630C>T p.H210= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs1213374199, COSV59545405; called by muse, mutect2
- GFRA1 | c.516G>A p.S172= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs371921058, COSV100815730; called by muse, mutect2, varscan2
- GHSR | c.384C>T p.Y128= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs200490484, COSV53842066, COSV99576678; called by muse, mutect2, varscan2
- GIMAP2 | c.117G>A p.G39= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV56234392; called by muse, mutect2, varscan2
- GPR137B | c.582A>T p.R194= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV100858312; called by muse, mutect2, varscan2
- HUWE1 | c.9309G>T p.R3103= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs1329092986, COSV99470632; called by muse, mutect2, varscan2
- ITPK1 | c.1029C>T p.A343= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs199744063; called by muse, mutect2
- KCNIP1 | c.327C>T p.F109= (on ENST00000411494 / NM_001034837.3; = p.F98= on NM_014592.4) | Silent (SNP) | VAF 57/165 reads (35%) | catalogued as rs780779650, COSV61080637, COSV61088655; called by muse, mutect2, varscan2
- LAMA2 | c.4188G>A p.P1396= | Silent (SNP) | VAF 22/103 reads (21%) | catalogued as rs369076029, COSV70344786, COSV70346493; called by muse, mutect2, varscan2
- MTMR14 | c.150C>A p.G50= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99931132; called by muse, mutect2, varscan2
- OR10S1 | c.75C>T p.F25= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV104440479, COSV73342700; called by muse, mutect2
- PCDHA12 | c.2175G>A p.A725= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV99165031; called by muse, mutect2, varscan2
- PKHD1L1 | c.1176T>C p.F392= | Silent (SNP) | VAF 28/296 reads (9%) | catalogued as COSV101005387; called by muse, mutect2
- PKHD1L1 | c.12405C>T p.V4135= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV101005388; called by muse, mutect2, varscan2
- PLCL2 | c.2910C>T p.P970= (on ENST00000615277 / NM_001144382.2; = p.P844= on NM_015184.5) | Silent (SNP) | VAF 44/167 reads (26%) | catalogued as rs766290779, COSV101196574, COSV67622757; called by muse, mutect2, varscan2
- PPP1R3F | c.675T>A p.G225= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99278399; called by muse, mutect2, varscan2
- RGS12 | c.729G>A p.T243= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs922684476, COSV100374757; called by muse, mutect2, varscan2
- RYR3 | c.5793T>G p.V1931= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV101212004; called by muse, mutect2, varscan2
- SPEF2 | c.1026C>T p.S342= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99213660; called by muse, mutect2, varscan2
- STAG2 | c.1704C>A p.A568= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV54371706; called by muse, mutect2, varscan2
- SUN1 | c.627G>A p.S209= (on ENST00000405266 / NM_001367651.1; = p.S159= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 51/211 reads (24%) | catalogued as rs370251394; called by muse, mutect2, varscan2
- TCF21 | c.372G>A p.A124= | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as rs201214778, COSV99399490; called by muse, mutect2, varscan2
- USP8 | c.831G>C p.L277= | Silent (SNP) | VAF 6/125 reads (5%) | catalogued as COSV100208739; called by muse, mutect2
- VHLL | c.10A>C p.R4= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV100372570; called by muse, mutect2, varscan2
- WSCD1 | c.747C>T p.R249= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as rs745867123, COSV58497046; called by muse, mutect2, varscan2
- ZNF479 | c.768T>C p.L256= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV100482477; called by muse, mutect2
- RBM44 | c.-98-1880G>A | Intron (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100389568; called by muse, mutect2, varscan2
- SSX5 | c.70-196C>T | Intron (SNP) | VAF 24/67 reads (36%) | catalogued as COSV100308612, COSV61255682; called by muse, mutect2, varscan2
